Gene-level copy-number profile of tumor specimen TCGA-A6-3810-01A from TCGA case TCGA-A6-3810, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.0 years (22,999 days).
Specimen TCGA-A6-3810-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.466c7664-9346-4735-9b66-16d10622beae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-3810-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c9a44b60-c12a-44e0-9562-eff8ff901de5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 8; copy number 2: 22,571; copy number 3: 19,962; copy number 4: 13,238; copy number 6: 2,626; copy number 9: 1,396; copy number 11: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-3810-01A-01D-A274-01): tumor purity 0.6, ploidy 3.16, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:20,160,593–20,186,206, 1 gene: SGO1.
- chr6:162,568,379–162,569,728, 1 gene: KRT8P44.
- chr16:6,380,476–6,874,005, 6 genes: AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,033 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:84,966,397–89,921,760, 101 genes, copy number 6–11 (broad region; genes not listed).
- chr6:89,950,116–89,953,186, 1 gene, copy number 11: AL121787.1.
- chr7:70,972–63,176,019, 1,086 genes, copy number 6 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 9 (broad region; genes not listed).
- chr20:87,250–16,053,197, 291 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
